Somatic mutation profile of tumor specimen MMRF_1865_1_BM_CD138pos (aliquot MMRF_1865_1_BM_CD138pos_T1_KBS5U_L05555) from MMRF case MMRF_1865, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.0 years (20,454 days).
Specimen MMRF_1865_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d0533b6-267b-4c9f-b492-ffd48674f09b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1865_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1865_1_PB_Whole_C3_KBS5U_L05577; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01fa4e0b-8f94-467f-8b23-29ce6e523e33

The open-access MAF lists 80 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 17, Silent 10, Intron 8, 5'Flank 3, Nonsense Mutation 2, 5'UTR 2, Frame Shift Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 142/467 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRD2 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs1317176937, COSV58340528; called by muse, mutect2, varscan2
- ARFGEF3 | c.4541G>A p.R1514Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs199906287, COSV52450670; called by muse, mutect2, varscan2
- BEND5 | c.1052del p.K351Rfs*15 | Frame Shift Del (DEL) | VAF 60/118 reads (51%) | catalogued as rs756345162, COSV65718189; called by mutect2, varscan2
- CCDC17 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1232756356, COSV99322350; called by muse, mutect2, varscan2
- CNTN6 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63192996; called by muse, mutect2, varscan2
- EIF4G1 | c.2962-8C>T | Splice Region (SNP) | VAF 78/190 reads (41%) | catalogued as rs773938941; called by muse, mutect2, varscan2
- GMPPA | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs759418965; called by muse, mutect2, varscan2
- GRIA4 | c.2635C>T p.P879S | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as rs779475985; called by muse, mutect2, varscan2
- IGHV2-70 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs373048671; called by muse, varscan2
- IGLV2-23 | c.115A>G p.I39V | Missense Mutation (SNP) | VAF 49/50 reads (98%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.338); catalogued as rs532888158; called by muse, mutect2, varscan2
- IGLV2-23 | c.218G>C p.S73T | Missense Mutation (SNP) | VAF 27/27 reads (100%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs371620489; called by muse, mutect2, varscan2
- IGLV5-37 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 108/207 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs757516840; called by muse, varscan2
- IGLV7-43 | c.218G>A p.S73N | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs368010383; called by muse, mutect2, varscan2
- KIAA1549L | c.3662C>T p.P1221L (on ENST00000321505; = p.P1518L on NM_012194.3) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778802245; called by muse, mutect2, varscan2
- MMP12 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs544068451, COSV100404828, COSV58262019; called by muse, mutect2
- OR13D1 | c.1002G>C p.K334N | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.225); catalogued as rs1203130986; called by muse, mutect2
- PCDHA6 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.929); catalogued as COSV67040130; called by muse, mutect2, varscan2
- RHPN2 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs771295262, COSV54278360; called by muse, mutect2, varscan2
- S1PR5 | c.980C>A p.S327Y | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV61013505; called by muse, mutect2, varscan2
- SCARB1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 80/271 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1406978035, COSV55551419; called by muse, mutect2, varscan2
- ZFP37 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV65287926; called by muse, mutect2, varscan2
- ZNF784 | c.499G>A p.V167I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs370290344; called by muse, varscan2
- CCDC130 | c.41A>G p.D14G | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELF1 | c.285A>C p.K95N | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- CYLD | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRGX | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GBP3 | c.713T>C p.L238P | Missense Mutation (SNP) | VAF 64/123 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPR63 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- HIPK2 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MRAP2 | c.528C>A p.Y176* | Nonsense Mutation (SNP) | VAF 83/213 reads (39%) | called by muse, mutect2, varscan2
- MYH2 | c.3992C>A p.A1331D | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR9G4 | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 70/166 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PI3 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PRKCE | c.1354T>C p.C452R | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RIMBP2 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RPL11 | c.95T>A p.L32Q (on ENST00000374550 / NM_001199802.1; = p.L33Q on NM_000975.5) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- SI | c.4610C>A p.S1537* | Nonsense Mutation (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- ZNF614 | c.748C>A p.L250M | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- DNAH12 | c.7845G>A p.L2615= (on ENST00000351747; = p.L3483= on NM_001366028.2) | Silent (SNP) | VAF 71/163 reads (44%) | called by muse, mutect2, varscan2
- DSCAML1 | c.3357C>T p.F1119= (on ENST00000321322; = p.F1059= on NM_020693.4) | Silent (SNP) | VAF 35/70 reads (50%) | catalogued as rs375863930; called by muse, mutect2, varscan2
- FNIP2 | c.1125G>A p.L375= | Silent (SNP) | VAF 116/230 reads (50%) | called by muse, mutect2, varscan2
- FSIP2 | c.11205T>C p.P3735= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as rs1324865021; called by muse, mutect2
- IGHV4-34 | c.237T>C p.H79= | Silent (SNP) | VAF 31/31 reads (100%) | catalogued as rs3814938; called by muse, varscan2
- IGLV1-44 | c.66G>A p.V22= | Silent (SNP) | VAF 98/207 reads (47%) | catalogued as rs544203333; called by muse, varscan2
- NYNRIN | c.3733C>A p.R1245= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as rs375519821; called by muse, mutect2, varscan2
- SLC35E4 | c.678G>T p.L226= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- SULT1A2 | c.261A>G p.P87= | Silent (SNP) | VAF 56/119 reads (47%) | called by muse, mutect2, varscan2
- ZNF418 | c.531G>A p.Q177= | Silent (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- ABCC9 | c.406+2296T>A | Intron (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1282G>A | RNA (SNP) | VAF 60/123 reads (49%) | catalogued as rs768938373; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.-277G>T | 5'UTR (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2
- C2orf49 | c.*1666A>T | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- CD47 | c.*2537T>G | 3'UTR (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- CXXC4 | c.*3214del | 3'UTR (DEL) | VAF 34/88 reads (39%) | called by mutect2, pindel, varscan2
- DIP2A | c.*136G>A | 3'UTR (SNP) | VAF 32/42 reads (76%) | catalogued as rs905664340; called by muse, mutect2, varscan2
- EIF4A2 | c.1079+423T>C | Intron (SNP) | VAF 134/228 reads (59%) | called by muse, mutect2, varscan2
- FAM172A | c.*1874C>G | 3'UTR (SNP) | VAF 8/121 reads (7%) | called by muse, mutect2
- FGD4 | c.*766T>G | 3'UTR (SNP) | VAF 69/156 reads (44%) | called by muse, mutect2, varscan2
- FZD4 | c.*5413A>C | 3'UTR (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- GLT1D1 | c.*1737G>A | 3'UTR (SNP) | VAF 56/163 reads (34%) | called by muse, mutect2, varscan2
- GPRC5C | c.*285G>A | 3'UTR (SNP) | VAF 32/69 reads (46%) | catalogued as rs895754808, COSV61238010; called by muse, mutect2, varscan2
- H3-3A | c.-23-137T>G | Intron (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- IKZF3 | c.*2851T>G | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- INSYN2B | c.-368G>T | 5'UTR (SNP) | VAF 3/37 reads (8%) | catalogued as rs1434576000; called by muse, mutect2
- LIPT2 | chr11:74497353 C>T | 5'Flank (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- MED28 | c.*8323T>A | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- MLLT11 | c.*28T>C | 3'UTR (SNP) | VAF 26/56 reads (46%) | called by muse, mutect2, varscan2
- NRP1 | c.1864+599C>T | Intron (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- PRICKLE2 | c.*3737A>T | 3'UTR (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- PTGS2 | c.971-19A>G | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as COSV66570959; called by muse, mutect2
- PTPRO | c.349+118T>A | Intron (SNP) | VAF 22/64 reads (34%) | called by muse, mutect2, varscan2
- QKI | c.934+924A>T | Intron (SNP) | VAF 114/242 reads (47%) | called by muse, mutect2, varscan2
- RAB17 | chr2:237595010 G>A | 5'Flank (SNP) | VAF 43/100 reads (43%) | catalogued as rs1053591415; called by muse, mutect2, varscan2
- RIBC1 | c.544+471G>A | Intron (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- SLC17A6 | c.*1098G>T | 3'UTR (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- SLC5A12 | c.*1915A>G | 3'UTR (SNP) | VAF 6/20 reads (30%) | catalogued as rs5024855, COSV68449360; called by muse, varscan2
- SPOCK1 | c.*2040T>A | 3'UTR (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- TMSB4X | chrX:12975304 G>A | 5'Flank (SNP) | VAF 112/113 reads (99%) | catalogued as COSV66081281; called by muse, mutect2, varscan2
- ZNF831 | c.*1230G>A | 3'UTR (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
